Somatic mutation profile of tumor specimen TARGET-40-PATMXR-01A (aliquot TARGET-40-PATMXR-01A-01D) from TARGET case TARGET-40-PATMXR, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 20.9 years (7,631 days).
Specimen TARGET-40-PATMXR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3930514a-8a61-45d0-b471-2ce14c57990a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PATMXR-10A (Blood Derived Normal), aliquot TARGET-40-PATMXR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab5239dc-399b-43ae-9058-c73a43f2d72f

The open-access MAF lists 99 somatic variants for this specimen: 60 protein-altering or splice-affecting, 13 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 13, Intron 13, 3'UTR 5, Frame Shift Del 5, RNA 4, In Frame Del 2, 5'UTR 2, Splice Site 1, 3'Flank 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.10142T>G p.I3381S | Missense Mutation (SNP) | VAF 211/549 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs1558693233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMTN | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as COSV59490180; called by muse, mutect2
- ANO6 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100263025; called by muse, mutect2
- ATRX | c.4564G>A p.E1522K | Missense Mutation (SNP) | VAF 159/348 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.701); catalogued as COSV64874759; called by muse, mutect2, varscan2
- CCDC150 | c.3067C>A p.Q1023K | Missense Mutation (SNP) | VAF 50/402 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs368280366; called by muse, mutect2, varscan2
- CHGB | c.253T>A p.L85M | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as rs1211653195; called by muse, varscan2
- COL7A1 | c.8295_8296del p.E2767Afs*22 | Frame Shift Del (DEL) | VAF 144/738 reads (20%) | catalogued as rs755580418; called by pindel, varscan2
- DOP1A | c.4181C>A p.T1394N | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1430217978; called by muse, mutect2
- KRTAP29-1 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 128/381 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs1392947878; called by muse, mutect2, varscan2
- NAP1L4 | c.958G>C p.G320R | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65881371; called by muse, mutect2, varscan2
- NCAM2 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.048); catalogued as COSV53087590; called by muse, mutect2
- RIBC1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 21/474 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); catalogued as COSV99394990; called by muse, mutect2
- SELE | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 176/381 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60973891; called by muse, mutect2, varscan2
- TNFRSF1B | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 90/519 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV66164470; called by muse, mutect2, varscan2
- XKR7 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs748725549, COSV73812885; called by muse, mutect2, varscan2
- ABCG1 | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 88/942 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADGRG2 | c.1743A>T p.R581S (on ENST00000379869 / NM_001079858.3; = p.R578S on NM_005756.4) | Missense Mutation (SNP) | VAF 189/370 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BDP1 | c.4343C>A p.A1448E | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CARMIL1 | c.1301C>G p.T434R | Missense Mutation (SNP) | VAF 257/421 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD4 | c.3904G>A p.E1302K (on ENST00000357008 / NM_001363606.2; = p.E1315K on NM_001273.5) | Missense Mutation (SNP) | VAF 171/1181 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL10A1 | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 34/647 reads (5%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2
- COL27A1 | c.2494G>A p.G832S | Missense Mutation (SNP) | VAF 131/541 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CYTL1 | c.153+2T>A p.X51_splice | Splice Site (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- DNAH6 | c.5080G>C p.G1694R | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- FAM20B | c.361_363del p.V121del | In Frame Del (DEL) | VAF 73/252 reads (29%) | called by pindel, varscan2
- GBP2 | c.614A>C p.K205T | Missense Mutation (SNP) | VAF 207/522 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- GIN1 | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.41); called by muse, mutect2
- GNE | c.953T>G p.F318C (on ENST00000396594 / NM_001128227.3; = p.F287C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/575 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GOLGA2 | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 162/276 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- GRAP2 | c.405T>A p.N135K | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNQ3 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 550/1018 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- LGR5 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 112/410 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEB5 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 124/455 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- MAP3K9 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 34/438 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- MC4R | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 102/410 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- MICAL3 | c.5375G>T p.S1792I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MKI67 | c.8993G>C p.R2998T | Missense Mutation (SNP) | VAF 39/674 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2
- MSMP | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MXRA5 | c.386T>G p.L129* | Nonsense Mutation (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- MYCBPAP | c.2195A>T p.N732I | Missense Mutation (SNP) | VAF 200/539 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- OGT | c.1529G>A p.S510N | Missense Mutation (SNP) | VAF 189/506 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- OR2G3 | c.792C>A p.D264E | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PCDHA13 | c.1873G>C p.G625R | Missense Mutation (SNP) | VAF 91/594 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PER2 | c.662_691del p.A221_L231delinsV | In Frame Del (DEL) | VAF 311/750 reads (41%) | called by mutect2, pindel, varscan2
- PHTF2 | c.530T>G p.L177R (on ENST00000248550 / NM_001366089.1; = p.L139R on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/524 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PKHD1L1 | c.11752C>A p.Q3918K | Missense Mutation (SNP) | VAF 126/649 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRPF38A | c.802A>G p.S268G | Missense Mutation (SNP) | VAF 40/635 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.95); called by muse, mutect2
- RRBP1 | c.1767_1782del p.A590Ifs*104 | Frame Shift Del (DEL) | VAF 76/446 reads (17%) | called by mutect2, pindel, varscan2
- SLC9A3R1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SRCAP | c.5094_5095del p.Q1698Hfs*149 | Frame Shift Del (DEL) | VAF 398/946 reads (42%) | called by mutect2, pindel, varscan2
- SRSF4 | c.682T>G p.S228A | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ST13 | c.687_688del p.K230Nfs*9 | Frame Shift Del (DEL) | VAF 43/197 reads (22%) | called by mutect2, pindel, varscan2
- TCF4 | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- TMEM63A | c.2173C>G p.P725A | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TRBC2 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2
- UBE2NL | c.194T>A p.M65K | Missense Mutation (SNP) | VAF 102/480 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by mutect2, varscan2
- USP24 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 185/419 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WASHC5 | c.989A>T p.Y330F | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ZMAT1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF711 | c.2246del p.N749Ifs*5 | Frame Shift Del (DEL) | VAF 49/256 reads (19%) | called by mutect2, pindel, varscan2
- ACSM2B | c.15A>G p.R5= | Silent (SNP) | VAF 83/305 reads (27%) | called by muse, mutect2, varscan2
- AJAP1 | c.711C>T p.T237= | Silent (SNP) | VAF 140/331 reads (42%) | catalogued as rs773983737; called by muse, varscan2
- ATP6V1C1 | c.141G>A p.T47= | Silent (SNP) | VAF 112/1032 reads (11%) | catalogued as rs1424437697, COSV67777777; called by muse, mutect2, varscan2
- CARD11 | c.1818C>T p.H606= | Silent (SNP) | VAF 70/345 reads (20%) | catalogued as rs571526682; called by muse, mutect2, varscan2
- DGKB | c.1461T>C p.P487= | Silent (SNP) | VAF 40/714 reads (6%) | catalogued as rs905245926; called by muse, mutect2
- LAMA1 | c.7902G>A p.T2634= | Silent (SNP) | VAF 156/218 reads (72%) | catalogued as rs756727988, COSV101055122; called by muse, mutect2, varscan2
- P2RY13 | c.63A>C p.A21= | Silent (SNP) | VAF 244/441 reads (55%) | called by muse, mutect2, varscan2
- PHTF2 | c.531G>T p.L177= (on ENST00000248550 / NM_001366089.1; = p.L139= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 94/526 reads (18%) | called by muse, varscan2
- PNPLA3 | c.882G>C p.V294= | Silent (SNP) | VAF 16/370 reads (4%) | called by muse, mutect2
- SLC4A11 | c.2415G>A p.V805= | Silent (SNP) | VAF 79/326 reads (24%) | called by muse, mutect2, varscan2
- USH2A | c.12846G>A p.L4282= | Silent (SNP) | VAF 102/224 reads (46%) | catalogued as COSV56331819; called by muse, mutect2, varscan2
- WSCD1 | c.390G>T p.L130= | Silent (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- ZNF804B | c.468C>A p.G156= | Silent (SNP) | VAF 117/273 reads (43%) | called by muse, mutect2, varscan2
- AIFM3 | c.1757+9G>T | Intron (SNP) | VAF 56/264 reads (21%) | called by muse, mutect2, varscan2
- AIFM3 | c.1757+10G>T | Intron (SNP) | VAF 55/263 reads (21%) | called by muse, mutect2, varscan2
- ANKRD20A17P | n.983A>C | RNA (SNP) | VAF 60/192 reads (31%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501820 ins CA | 5'Flank (INS) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- ARHGEF5 | c.3155-63G>C | Intron (SNP) | VAF 111/574 reads (19%) | called by muse, mutect2, varscan2
- CCDC138 | c.*29T>C | 3'UTR (SNP) | VAF 92/229 reads (40%) | called by muse, mutect2, varscan2
- DBNDD2 | c.160-112G>C | Intron (SNP) | VAF 131/711 reads (18%) | called by muse, mutect2, varscan2
- DDA1 | c.136+134C>G | Intron (SNP) | VAF 25/33 reads (76%) | called by muse, mutect2, varscan2
- DDRGK1 | c.-50A>T | 5'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- EDIL3 | c.*13T>A | 3'UTR (SNP) | VAF 13/342 reads (4%) | catalogued as COSV56905767; called by muse, mutect2
- ELP4 | chr11:31788685 C>T | 3'Flank (SNP) | VAF 10/235 reads (4%) | called by muse, mutect2
- GABRG2 | c.1249-556T>C | Intron (SNP) | VAF 49/139 reads (35%) | called by muse, mutect2, varscan2
- HAO2 | c.-8-374G>C | Intron (SNP) | VAF 117/728 reads (16%) | called by muse, mutect2, varscan2
- MZT2A | c.*37A>G | 3'UTR (SNP) | VAF 34/1092 reads (3%) | called by muse, mutect2
- PTPA | c.999+233_999+237del | Intron (DEL) | VAF 18/37 reads (49%) | called by mutect2, pindel, varscan2
- PTPRD | c.3056-21_3056-20del | Intron (DEL) | VAF 20/192 reads (10%) | called by mutect2, pindel, varscan2
- REG1A | c.184-26G>A | Intron (SNP) | VAF 272/677 reads (40%) | catalogued as COSV52070119; called by muse, mutect2, varscan2
- SLC29A4P2 | n.1037A>C | RNA (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2
- SLC9B1P4 | n.119A>G | RNA (SNP) | VAF 26/330 reads (8%) | catalogued as rs1231346369; called by muse, mutect2
- SORBS2 | c.684+7652C>T | Intron (SNP) | VAF 15/104 reads (14%) | catalogued as rs566236409, COSV52996022; called by muse, mutect2, varscan2
- SYNGR3 | c.*645G>C | 3'UTR (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.-61G>A | 5'UTR (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- TOMM5 | c.*9del | 3'UTR (DEL) | VAF 26/221 reads (12%) | called by mutect2, pindel, varscan2
- UBTFL2 | n.356C>T | RNA (SNP) | VAF 173/367 reads (47%) | called by muse, mutect2, varscan2
- WASH6P | c.301-53C>T | Intron (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- ZNF410 | c.170-107T>C | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
